Somatic mutation profile of tumor specimen HTMCP-03-06-02379-01A (aliquot HTMCP-03-06-02379-01A-01D-10409) from CGCI case HTMCP-03-06-02379, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02379-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d93ee2bd-73f2-4061-bffb-5d0e5e232566.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02379-10A (Blood Derived Normal), aliquot HTMCP-03-06-02379-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a47e853a-af99-4cb0-bf63-a1573c7d6044

The open-access MAF lists 674 somatic variants for this specimen: 494 protein-altering or splice-affecting, 142 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 142, Frame Shift Del 117, Intron 25, Frame Shift Ins 21, Nonsense Mutation 17, Splice Region 13, In Frame Del 7, Splice Site 5, 3'Flank 4, RNA 3, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4395G>A p.W1465* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs1057518069; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL11A2 | c.966del p.T323Qfs*59 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs748440351, COSV59498865; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 38/108 reads (35%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 119/161 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 67/243 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 58/194 reads (30%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 37/133 reads (28%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 143/268 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660535, CM041823, CM110163, COSV64289150, COSV64290215, COSV64293195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 33/148 reads (22%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.35703dup p.P11902Tfs*13 (on ENST00000591111; = p.P4478Tfs*13 on NM_003319.4) | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | catalogued as rs1553754743; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.4541C>T p.T1514M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs776797665; called by muse, varscan2
- ABCC6 | c.3563C>T p.T1188M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs777163389; called by muse, mutect2, varscan2
- ABL2 | c.1712G>A p.R571Q (on ENST00000502732 / NM_007314.4; = p.R556Q on NM_005158.5) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs747400049, COSV61013590, COSV61018775; called by muse, mutect2, varscan2
- AC244197.3 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as rs370125505, COSV100558049; called by muse, mutect2, varscan2
- ACACB | c.4943G>A p.R1648H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777367863; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 54/90 reads (60%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs138024512; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4702C>T p.R1568C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747493274; called by muse, mutect2, varscan2
- ADGRB2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173930520; called by muse, mutect2, varscan2
- ADGRB3 | c.227del p.K76Rfs*23 | Frame Shift Del (DEL) | VAF 64/227 reads (28%) | catalogued as COSV65402270; called by mutect2, pindel, varscan2
- ADGRF1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs779914905; called by muse, mutect2, varscan2
- ADGRG2 | c.1061C>T p.A354V (on ENST00000379869 / NM_001079858.3; = p.A351V on NM_005756.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1254226753, COSV61339022, COSV61341057; called by muse, mutect2, varscan2
- ADGRL3 | c.4544C>A p.P1515Q (on ENST00000506720 / NM_001322402.2; = p.P1404Q on NM_015236.6) | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.519); catalogued as rs186336773, COSV72231711; called by muse, mutect2, varscan2
- AHI1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267610948, COSV55630978, COSV55637376; called by muse, mutect2, varscan2
- AKAP9 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs373876340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKFY1 | c.2497C>T p.R833* (on ENST00000341657 / NM_001330063.2; = p.R834* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 62/147 reads (42%) | catalogued as rs1438927726, COSV58917342; called by muse, mutect2, varscan2
- ANKRD52 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1294885547; called by muse, mutect2, varscan2
- AP2A1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.226); catalogued as rs747545364, COSV62818635; called by muse, mutect2, varscan2
- APC | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs566005215, COSV57348747, COSV57376259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARGFX | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1382480652; called by muse, mutect2, varscan2
- ARHGAP11A | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs751204257, COSV100853315; called by muse, mutect2, varscan2
- ARHGAP23 | c.3447+4C>T | Splice Region (SNP) | VAF 30/117 reads (26%) | catalogued as rs376864985; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 121/174 reads (70%) | catalogued as rs761154268; called by mutect2, varscan2
- ATAD5 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1294728867, COSV58972616; called by muse, mutect2, varscan2
- ATM | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as CS145383, COSV99069698, COSV99587703; called by muse, varscan2
- ATP1A2 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV63404956; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAZ2A | c.4697G>A p.R1566Q | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs192786002; called by muse, varscan2
- BCAS3 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758268067, COSV66776666; called by muse, mutect2, varscan2
- BCOR | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs780396086, COSV60701707; called by muse, mutect2, varscan2
- BCR | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs774413004; called by muse, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 30/84 reads (36%) | catalogued as rs749043197; called by mutect2, varscan2
- C2CD3 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs531608642; called by muse, mutect2, varscan2
- C7orf31 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370479494; called by muse, mutect2, varscan2
- CABIN1 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1569243251, COSV54077629; called by muse, mutect2, varscan2
- CACNA2D3 | c.437del p.L146Wfs*9 | Frame Shift Del (DEL) | VAF 62/216 reads (29%) | catalogued as COSV55589697; called by mutect2, pindel, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs201838505; called by mutect2, varscan2
- CASKIN2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1471819376, COSV58690016; called by muse, mutect2
- CASP8 | c.455T>C p.L152P (on ENST00000432109 / NM_033355.3; = p.L184P on NM_001228.4) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51846631; called by muse, mutect2, varscan2
- CCDC114 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs137875815; called by muse, mutect2, varscan2
- CCDC171 | c.2075del p.N692Tfs*5 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs1463058740; called by mutect2, pindel, varscan2
- CCDC33 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs201882376; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC40 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs769950440; called by muse, mutect2, varscan2
- CDH26 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV99723158; called by muse, mutect2, varscan2
- CDH7 | c.427del p.I143Ffs*33 | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | catalogued as COSV59898501; called by pindel, varscan2
- CELSR2 | c.8479del p.L2827Ffs*66 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs35081717; called by mutect2, pindel, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 97/205 reads (47%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CERCAM | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761539491; called by muse, mutect2
- CFH | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs145347741, CM100538; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/141 reads (38%) | catalogued as rs761731080; called by mutect2, varscan2
- CNTN6 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs147761774; called by muse, mutect2, varscan2
- COL22A1 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309497590, COSV57335778; called by muse, mutect2, varscan2
- COL5A3 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as rs369495078; called by muse, varscan2
- COL6A2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145140058, COSV56002853; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.7322G>A p.R2441Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753090057, COSV55093722; called by muse, mutect2, varscan2
- COL6A6 | c.2647G>T p.G883C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62028229; called by muse, mutect2, varscan2
- COL7A1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs761630796; called by muse, mutect2, varscan2
- CPED1 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs760733370; called by muse, mutect2, varscan2
- CSMD2 | c.7339C>T p.R2447C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763797256, COSV104384984; called by muse, mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs1300471016; called by mutect2, pindel, varscan2
- CTTN | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs200945890; called by muse, mutect2, varscan2
- DCAF12L2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV63580780; called by muse, mutect2, varscan2
- DCAF8L2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs377420810, COSV70548064; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | catalogued as COSV101373865, COSV69362732; called by pindel, varscan2
- DCLRE1C | c.2053del p.R685Efs*6 (on ENST00000378278 / NM_001350965.2; = p.R570Efs*6 on NM_022487.4) | Frame Shift Del (DEL) | VAF 46/206 reads (22%) | catalogued as rs915913541; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 110/224 reads (49%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs772416332; called by mutect2, varscan2
- DGKG | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs574769788, COSV53964855; called by muse, mutect2, varscan2
- DGKI | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773058095, COSV55949015, COSV99937841, COSV99938434; called by muse, mutect2, varscan2
- DIP2A | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs558662306, COSV59486284; called by muse, mutect2, varscan2
- DISP1 | c.3444del p.K1148Nfs*26 | Frame Shift Del (DEL) | VAF 87/272 reads (32%) | catalogued as rs1478802964; called by mutect2, pindel, varscan2
- DNAH17 | c.8912G>A p.R2971H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs747523018; called by muse, varscan2
- DNAH2 | c.3868C>T p.R1290C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774774306, COSV66716539, COSV66720980; called by muse, mutect2, varscan2
- DNAJC13 | c.5678G>A p.R1893Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs139626514; called by muse, mutect2, varscan2
- DOCK3 | c.5499del p.G1834Vfs*63 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | catalogued as rs34788750; called by mutect2, pindel, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2
- DSCAML1 | c.3625C>T p.R1209W (on ENST00000321322; = p.R1149W on NM_020693.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs373841969; called by muse, varscan2
- DYNC2H1 | c.11942G>A p.R3981H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs755554260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F7 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 69/134 reads (51%) | catalogued as rs760841332, COSV59738524; called by muse, mutect2, varscan2
- EEF1A1 | c.1265-6del | Splice Region (DEL) | VAF 54/84 reads (64%) | catalogued as rs530302960; called by mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs773311790; called by mutect2, varscan2
- EMILIN1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs765499541, COSV66694553; called by muse, mutect2, varscan2
- EPB41 | c.1720G>A p.V574I (on ENST00000343067 / NM_001166005.2; = p.V365I on NM_004437.4) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs774641770; called by muse, mutect2, varscan2
- EPHB4 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1328611138, COSV62270373; called by muse, mutect2
- ERCC6 | c.2382G>T p.Q794H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV63391664; called by muse, mutect2, varscan2
- EXO1 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560299246; called by muse, mutect2, varscan2
- FAT1 | c.6233C>T p.A2078V | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as rs758885671; called by muse, mutect2, varscan2
- FBF1 | c.2357G>A p.R786Q (on ENST00000586717; = p.R800Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs201452359; called by muse, varscan2
- FBN1 | c.5458C>T p.R1820C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV57331693; called by muse, mutect2, varscan2
- FBN2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs559772944; called by muse, mutect2, varscan2
- FCGBP | c.10129G>A p.D3377N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs371274378; called by muse, mutect2, varscan2
- FLRT2 | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1263829616; called by muse, mutect2, varscan2
- FN1 | c.901del p.Q301Sfs*23 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV60565992; called by mutect2, pindel, varscan2
- GCM2 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.379); catalogued as rs146395801, CM099925; called by muse, mutect2, varscan2
- GFPT2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766622009, COSV53812991; called by muse, mutect2, varscan2
- GLDC | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1172061571, COSV58685737; called by muse, mutect2, varscan2
- GPATCH3 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767698969, COSV64652165; called by muse, mutect2, varscan2
- GREB1 | c.4634C>A p.P1545Q | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52180587; called by muse, mutect2, varscan2
- GRIK2 | c.2185C>A p.L729I | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as COSV59710910, COSV59765428; called by muse, mutect2, varscan2
- GRIN3A | c.1730A>G p.Y577C | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761191544; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs747773579; called by mutect2, varscan2
- GTF3C1 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374729096; called by muse, mutect2, varscan2
- GTF3C1 | c.5056G>A p.A1686T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs2229355; called by muse, mutect2, varscan2
- GUCY2C | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376847075; called by muse, mutect2, varscan2
- HECW1 | c.4561C>T p.R1521C | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs750772022, COSV67821164; called by muse, mutect2, varscan2
- HECW2 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.166); catalogued as rs541818813, COSV53675351; called by muse, mutect2, varscan2
- HERC2 | c.10817G>A p.R3606H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs774314480; called by muse, mutect2, varscan2
- HHIPL1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as rs549263452, COSV58090412; called by muse, mutect2, varscan2
- HIP1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417171; called by muse, mutect2, varscan2
- HSPG2 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs768633308, COSV65930349; called by muse, mutect2, varscan2
- IFT172 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs146575848; called by muse, mutect2, varscan2
- IGF2R | c.6451G>T p.G2151* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100807392; called by muse, mutect2, varscan2
- IKBIP | c.626del p.N209Ifs*3 | Frame Shift Del (DEL) | VAF 88/219 reads (40%) | catalogued as rs752553685; called by mutect2, pindel, varscan2
- ING4 | c.500C>T p.T167I (on ENST00000396807 / NM_001127582.2; = p.T166I on NM_016162.4) | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs142380796; called by muse, mutect2, varscan2
- IRS4 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100929784; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as rs202218284, COSV56442044, COSV56442907; called by muse, mutect2, varscan2
- ITIH6 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as rs754153112, COSV54489395; called by muse, mutect2, varscan2
- JAKMIP1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.395); catalogued as COSV51546858; called by muse, mutect2, varscan2
- KATNIP | c.3158C>T p.T1053M | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199699389, COSV55176706; called by muse, mutect2, varscan2
- KBTBD7 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs552332866; called by muse, mutect2, varscan2
- KBTBD7 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as rs773202669, COSV101068062; called by muse, mutect2, varscan2
- KCNH4 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916181; called by muse, mutect2, varscan2
- KDM2B | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs782601402, COSV65641655; called by muse, mutect2, varscan2
- KIAA1549 | c.3010G>A p.G1004S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs781225945; called by muse, mutect2, varscan2
- KIAA1549L | c.1466C>A p.P489H (on ENST00000321505; = p.P786H on NM_012194.3) | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV55778401; called by muse, mutect2, varscan2
- KIF1B | c.5173G>A p.V1725I (on ENST00000377086 / NM_001365952.1; = p.V1679I on NM_015074.3) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753477704, COSV55812870; called by muse, mutect2, varscan2
- KIR3DL3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs549649199; called by muse, mutect2, varscan2
- KNTC1 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1163233829, COSV100338414; called by muse, mutect2, varscan2
- KNTC1 | c.6305A>G p.Q2102R | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs367860451; called by muse, mutect2, varscan2
- LAMC3 | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs769688460, COSV62654360; called by muse, mutect2
- LARGE1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs780394465, COSV100504883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIG3 | c.2115C>T p.G705= | Splice Region (SNP) | VAF 19/54 reads (35%) | catalogued as rs752457103, COSV52009117; called by muse, mutect2, varscan2
- LMO7 | c.1165C>T p.R389C (on ENST00000357063; = p.R119C on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/379 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760920054, COSV58535957; called by muse, mutect2, varscan2
- LMO7 | c.2206del p.S736Vfs*69 (on ENST00000357063; = p.S417Vfs*69 on NM_005358.5) | Frame Shift Del (DEL) | VAF 47/191 reads (25%) | catalogued as rs34219193; called by mutect2, pindel, varscan2
- LRP8 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.844); catalogued as rs777992531; called by muse, mutect2, varscan2
- LRRC7 | c.2533C>T p.R845C (on ENST00000651989 / NM_001370785.2; = p.R812C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1182861744, COSV50414820; called by muse, mutect2, varscan2
- MAML1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); catalogued as rs374784640; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MED12 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100377204; called by muse, mutect2, varscan2
- MGA | c.7306C>T p.R2436C (on ENST00000219905 / NM_001164273.1; = p.R2227C on NM_001080541.2) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54957604, COSV54963876; called by muse, mutect2, varscan2
- MIB2 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs371323653; called by muse, mutect2, varscan2
- MMP16 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs866043551, COSV54176946, COSV99688155; called by muse, mutect2, varscan2
- MON2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756901762, COSV54812001, COSV99743569; called by muse, mutect2, varscan2
- MS4A14 | c.463_464del p.F155Hfs*14 | Frame Shift Del (DEL) | VAF 82/253 reads (32%) | catalogued as rs752970400; called by mutect2, pindel, varscan2
- MSH2 | c.793-1G>C p.X265_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | catalogued as CS092662, CS101437; called by muse, mutect2, varscan2
- MTMR1 | c.1614del p.F538Lfs*32 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | catalogued as rs34208120; called by mutect2, pindel, varscan2
- MTOR | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63872026; called by muse, mutect2, varscan2
- MUC12 | c.6203C>T p.T2068M (on ENST00000379442; = p.T1925M on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/1283 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.788); catalogued as rs1294031570; called by muse, mutect2
- MUC2 | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.08); catalogued as rs776041994; called by muse, mutect2, varscan2
- MVP | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs753931360, COSV62422379; called by muse, mutect2, varscan2
- MYF6 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57353342; called by muse, mutect2, varscan2
- MYH7B | c.1630_1632del p.E544del | In Frame Del (DEL) | VAF 36/162 reads (22%) | catalogued as rs745664327; called by pindel, varscan2
- MYH7B | c.3893G>T p.R1298L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52684309; called by muse, mutect2, varscan2
- MYO1H | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs377151314; called by muse, mutect2, varscan2
- MYOM1 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs372147749; called by muse, mutect2, varscan2
- MYRIP | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs199926745; called by muse, mutect2, varscan2
- NABP2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363779419; called by muse, mutect2, varscan2
- NALCN | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1420619266, COSV51918435; called by muse, mutect2, varscan2
- NDOR1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs147069763; called by muse, mutect2, varscan2
- NEB | c.13952C>T p.T4651M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763526873, COSV50914224; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs759081520; called by mutect2, varscan2
- NOTCH2 | c.4819C>T p.R1607C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs761870508, COSV99866931; called by muse, mutect2, varscan2
- NRCAM | c.2024G>A p.S675N (on ENST00000379028 / NM_001371124.1; = p.S659N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs758454437; called by muse, mutect2, varscan2
- NRXN3 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs781273991; called by muse, mutect2, varscan2
- NSUN4 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1557737845; called by muse, mutect2, varscan2
- NUMA1 | c.5548G>A p.A1850T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as rs1470504132; called by muse, mutect2, varscan2
- NUMA1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs754214935, COSV61183285; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 52/177 reads (29%) | catalogued as rs751106039; called by mutect2, varscan2
- P2RY13 | c.702dup p.V235Sfs*3 | Frame Shift Ins (INS) | VAF 78/276 reads (28%) | catalogued as rs771457469; called by mutect2, varscan2
- PAPPA2 | c.5055dup p.S1686Qfs*2 | Frame Shift Ins (INS) | VAF 57/183 reads (31%) | catalogued as rs747970462; called by mutect2, varscan2
- PCK1 | c.1506G>C p.Q502H | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60126665; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 38/76 reads (50%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs201885668; called by muse, mutect2
- PER1 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs199551108; called by muse, mutect2, varscan2
- PGS1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs778084361; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF20L1 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs760704893; called by muse, mutect2, varscan2
- PHIP | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753204166; called by muse, mutect2, varscan2
- PHLPP2 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1248796507; called by muse, mutect2, varscan2
- PI4KA | c.6017del p.G2006Afs*52 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as COSV55402777; called by mutect2, pindel, varscan2
- PKD1L1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs773395643, COSV99220888; called by muse, mutect2, varscan2
- PLEKHG2 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs374823888; called by muse, varscan2
- PLEKHM2 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs746715478, COSV101009041; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB1 | c.6095C>T p.P2032L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777535314, COSV56489456; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNB3 | c.3016G>A p.A1006T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs189684685; called by muse, mutect2, varscan2
- PLXNB3 | c.5101-4G>A | Splice Region (SNP) | VAF 33/75 reads (44%) | catalogued as rs782404774; called by muse, mutect2, varscan2
- PML | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs1567130417, COSV51447576; called by muse, mutect2, varscan2
- POM121 | c.1666G>A p.D556N (on ENST00000434423; = p.D291N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as rs1390075952; called by mutect2, varscan2
- PPFIA2 | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1316742650, COSV61040678; called by muse, varscan2
- PRDM15 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781202777, COSV54149167; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 44/130 reads (34%) | catalogued as rs753143066; called by mutect2, varscan2
- PRX | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs149241078; called by muse, mutect2, varscan2
- PTPRQ | c.4564G>A p.E1522K (on ENST00000616559; = p.E1480K on NM_001145026.2) | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.396); catalogued as rs1455656996, COSV57048175; called by muse, mutect2, varscan2
- PYGO2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs1460266858, COSV63756687; called by muse, mutect2, varscan2
- RABEP2 | c.1092G>A p.A364= | Splice Region (SNP) | VAF 9/42 reads (21%) | catalogued as rs368493934; called by muse, mutect2, varscan2
- RALGAPA1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746208135; called by muse, mutect2, varscan2
- RASGRP4 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757409206, COSV99384994; called by muse, mutect2, varscan2
- RNF40 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs755842754, COSV61216848; called by muse, mutect2, varscan2
- RP1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 158/328 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747898942, COSV55114303; called by muse, mutect2, varscan2
- RPA1 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs865781874, COSV99627894; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 59/92 reads (64%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA3 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs1210859060, COSV65387383; called by muse, mutect2, varscan2
- RPS6KA3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV101084476; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 62/191 reads (32%) | catalogued as rs749201569; called by mutect2, varscan2
- RYR3 | c.4667G>A p.R1556Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs944509543, COSV66799121; called by muse, mutect2, varscan2
- SCN4A | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs768902973; called by muse, mutect2, varscan2
- SCN5A | c.4876C>T p.R1626C (on ENST00000333535 / NM_198056.3; = p.R1625C on NM_000335.5) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918933961, COSV61118793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.5003A>G p.Y1668C (on ENST00000303354; = p.Y1657C on NM_002977.3) | Missense Mutation (SNP) | VAF 49/431 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754141856; called by muse, mutect2
- SETD1A | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567353627, COSV52689838, COSV52690050; called by muse, mutect2, varscan2
- SHROOM3 | c.2243C>A p.P748H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV99935685; called by muse, mutect2, varscan2
- SIK1 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs770153649; called by muse, mutect2, varscan2
- SIPA1L1 | c.4386_4388del p.S1468del | In Frame Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs781296708; called by pindel, varscan2
- SIPA1L2 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs779583701, COSV53383513; called by muse, mutect2, varscan2
- SLC12A2 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1221638323; called by muse, mutect2, varscan2
- SMAD5 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs774538677, COSV72597681; called by muse, mutect2, varscan2
- SNRPD2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1424068444; called by muse, mutect2, varscan2
- SPAG17 | c.4529G>A p.C1510Y | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770774268; called by muse, mutect2, varscan2
- SPEF2 | c.3749A>G p.E1250G | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100607547; called by muse, mutect2, varscan2
- SPEG | c.2674G>A p.V892M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753006280; called by muse, mutect2, varscan2
- SULF1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs145127325; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 66/248 reads (27%) | catalogued as rs570102997; called by mutect2, varscan2
- TACC2 | c.7271C>T p.T2424M (on ENST00000334433; = p.T502M on NM_006997.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs907564066; called by muse, mutect2, varscan2
- TANC2 | c.2358G>A p.P786= | Splice Region (SNP) | VAF 11/96 reads (11%) | catalogued as rs779580227; called by muse, mutect2, varscan2
- TAT | c.950del p.L317Wfs*11 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | catalogued as COSV63532632, COSV63533190; called by mutect2, pindel, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 62/150 reads (41%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TECPR2 | c.3125C>T p.T1042M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs766200104; called by muse, mutect2, varscan2
- TENM1 | c.7853G>A p.R2618Q | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758694053; called by muse, mutect2, varscan2
- TENM3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV69316498; called by muse, mutect2, varscan2
- TENM3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs374213747; called by muse, mutect2, varscan2
- TET3 | c.4120dup p.L1374Pfs*35 | Frame Shift Ins (INS) | VAF 15/85 reads (18%) | catalogued as rs747653420; called by mutect2, pindel, varscan2
- TEX2 | c.2210C>T p.P737L (on ENST00000583097 / NM_001288733.2; = p.P744L on NM_018469.5) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs750661894, COSV51983878; called by muse, mutect2, varscan2
- THSD1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as rs377555312, COSV51630041; called by muse, mutect2, varscan2
- TLN2 | c.4693G>A p.A1565T | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs143603462; called by muse, mutect2, varscan2
- TMEM131 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.753); catalogued as rs766985459, COSV51776042; called by muse, mutect2, varscan2
- TMEM63B | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs781648674; called by muse, mutect2, varscan2
- TMEM79 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766683496, COSV55295956; called by muse, mutect2
- TMPRSS6 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as rs371788844; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNN | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776764321, COSV53431884; called by muse, mutect2, varscan2
- TNXB | c.13454G>A p.R4485H (on ENST00000647633; = p.R4238H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs746223901; called by muse, mutect2, varscan2
- TOGARAM2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757999432, COSV65421885; called by muse, mutect2, varscan2
- TOP3B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769874024, COSV64116280; called by muse, mutect2, varscan2
- TOPBP1 | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs759938150, COSV53438107; called by muse, mutect2, varscan2
- TPO | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as COSV61107811; called by muse, mutect2, varscan2
- TPRN | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs758323082, COSV58808920; called by muse, mutect2, varscan2
- TRAF7 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs750329755, COSV58213392; called by muse, varscan2
- TRIM33 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs761615457, COSV61825789; called by muse, mutect2, varscan2
- TRPA1 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs761428917, COSV51569085; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.2560_2561del p.R854Gfs*10 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV57883906; called by pindel, varscan2
- TTLL5 | c.181+5G>A | Splice Region (SNP) | VAF 33/99 reads (33%) | catalogued as rs762077466; called by muse, mutect2, varscan2
- TTN | c.2852del p.N951Mfs*2 (on ENST00000591111; = p.N905Mfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as COSV59940566; called by mutect2, pindel, varscan2
- UBR4 | c.10273C>T p.R3425C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775894038, COSV100921425; called by muse, mutect2, varscan2
- UNC13B | c.4732G>A p.V1578M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745898914; called by muse, mutect2, varscan2
- UNC13C | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs751934604, COSV99517335; called by muse, mutect2, varscan2
- UNC13D | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1194073667, COSV52884190; called by muse, mutect2, varscan2
- USP19 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as rs376820680; called by muse, mutect2, varscan2
- USP26 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs764088622, CM164474, COSV63708038; called by muse, mutect2, varscan2
- USP49 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576361896, COSV51898222; called by muse, mutect2, varscan2
- VPS13B | c.4460A>G p.H1487R | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.371); catalogued as rs1267695807; called by muse, mutect2, varscan2
- VPS13C | c.1847C>T p.P616L (on ENST00000644861 / NM_020821.3; = p.P573L on NM_017684.5) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745918169; called by muse, mutect2, varscan2
- VWF | c.4706G>A p.R1569H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769025840, COSV54618464; called by muse, mutect2, varscan2
- VXN | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1291216329; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs773064295, COSV51967888; called by mutect2, varscan2
- WDFY4 | c.5420G>A p.R1807H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200503448, COSV55421510; called by muse, varscan2
- WDR49 | c.1940G>A p.R647H (on ENST00000308378 / NM_001366158.1; = p.R988H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs201853983, COSV100392208, COSV57712783; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.4571C>T p.P1524L (on ENST00000673675 / NM_001371589.1; = p.P429L on NM_021241.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs374280950; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WSCD2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs950568945, COSV54585750; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 83/162 reads (51%) | catalogued as rs762052135; called by mutect2, varscan2
- ZBED4 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs747120999; called by muse, mutect2, varscan2
- ZHX3 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs749654315; called by muse, mutect2, varscan2
- ZMYM4 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs777585345; called by muse, mutect2, varscan2
- ZNF18 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as rs777203770; called by muse, mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF366 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as rs140626285; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 51/138 reads (37%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF814 | c.1050dup p.H351Tfs*3 | Frame Shift Ins (INS) | VAF 110/520 reads (21%) | catalogued as rs562075498; called by mutect2, varscan2
- ZNFX1 | c.4453C>T p.P1485S | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs746976084; called by muse, mutect2, varscan2
- ABCA13 | c.9761C>T p.A3254V | Missense Mutation (SNP) | VAF 93/124 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ACAP2 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACLY | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.364del p.A122Lfs*8 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ADAMTS2 | c.1533dup p.C512Lfs*10 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- ADAR | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ADCY1 | c.1425del p.F475Lfs*14 | Frame Shift Del (DEL) | VAF 110/193 reads (57%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.459dup p.E154* | Frame Shift Ins (INS) | VAF 59/185 reads (32%) | called by mutect2, varscan2
- AJM1 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- AKAP12 | c.3623del p.G1208Afs*36 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | called by mutect2, pindel, varscan2
- AKAP13 | c.6090del p.F2030Lfs*6 (on ENST00000394518 / NM_007200.5; = p.F2034Lfs*6 on NM_006738.6) | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- ANK2 | c.7433T>C p.M2478T | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4215del p.K1405Nfs*10 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.5965G>A p.V1989I | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANO8 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.145); called by muse, mutect2
- ARFGAP3 | c.273del p.H92Ifs*69 | Frame Shift Del (DEL) | VAF 35/130 reads (27%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.3505del p.I1169* | Frame Shift Del (DEL) | VAF 46/354 reads (13%) | called by pindel, varscan2
- ARHGAP35 | c.2814del p.F938Lfs*10 | Frame Shift Del (DEL) | VAF 64/199 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.576del p.K192Nfs*3 | Frame Shift Del (DEL) | VAF 68/228 reads (30%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- ARID2 | c.5333del p.N1778Ifs*13 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- ATP1A3 | c.2095del p.Q699Sfs*19 (on ENST00000545399 / NM_001256214.2; = p.Q686Sfs*19 on NM_152296.5) | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.5757del p.K1920Rfs*93 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- BCORL1 | c.5041_5042insA p.P1681Hfs*5 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.2336_2339del p.T779Sfs*23 | Frame Shift Del (DEL) | VAF 38/146 reads (26%) | called by pindel, varscan2
- BORCS6 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRD1 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BRPF3 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CADPS | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CANX | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CCDC158 | c.1530_1531dup p.A511Efs*19 | Frame Shift Ins (INS) | VAF 46/137 reads (34%) | called by mutect2, varscan2
- CCDC160 | c.194A>T p.K65I | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CDC42EP1 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CDK16 | c.17_19del p.K6del | In Frame Del (DEL) | VAF 15/45 reads (33%) | called by pindel, varscan2
- CENPF | c.996del p.E333Rfs*4 | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- CFAP46 | c.4089del p.E1364Rfs*56 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- CHD7 | c.1953del p.D652Tfs*59 | Frame Shift Del (DEL) | VAF 33/205 reads (16%) | called by mutect2, varscan2
- CHL1 | c.800dup p.L267Ffs*7 (on ENST00000397491 / NM_001253387.1; = p.L283Ffs*7 on NM_006614.4) | Frame Shift Ins (INS) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- CNTRL | c.2611_2613del p.E871del | In Frame Del (DEL) | VAF 30/94 reads (32%) | called by pindel, varscan2
- COL4A5 | c.3436G>T p.G1146* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- COL5A3 | c.2657dup p.G887Wfs*5 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- CPSF1 | c.3745-3del | Splice Region (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- CSMD2 | c.9245A>G p.E3082G | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSTF3 | c.1317del p.K439Nfs*33 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | called by mutect2, pindel, varscan2
- CYTH3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCC | c.2339A>G p.Y780C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND5B | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 143/274 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DHX9 | c.1970dup p.L657Ffs*44 | Frame Shift Ins (INS) | VAF 42/123 reads (34%) | called by mutect2, varscan2
- DNMBP | c.2160G>T p.E720D | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DNMT1 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- DNMT3A | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DOCK1 | c.2386del p.X796_splice | Splice Site (DEL) | VAF 29/114 reads (25%) | called by mutect2, pindel, varscan2
- DOCK4 | c.869del p.K290Rfs*23 | Frame Shift Del (DEL) | VAF 119/304 reads (39%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4713del p.F1571Lfs*19 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by pindel, varscan2
- DYNC1H1 | c.13729C>A p.L4577M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DYNC2H1 | c.4792G>A p.A1598T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EML2 | c.710del p.G237Afs*3 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- ENAH | c.1485A>C p.K495N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EP300 | c.4550T>G p.I1517S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- EZH1 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM8A1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAN1 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- FARP1 | c.2621del p.P874Lfs*20 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- FBXO41 | c.784_786del p.K262del | In Frame Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- FIP1L1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXP1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- FRMPD3 | c.861+8C>T | Splice Region (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- FZD7 | c.1390C>A p.L464M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDPD4 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- GEMIN5 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNAI1 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 146/296 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPAT2 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPSM1 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPSM2 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- GTF3C1 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- HERC2 | c.847del p.L283Cfs*21 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- HLA-A | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HUWE1 | c.9924dup p.R3309Afs*2 | Frame Shift Ins (INS) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- IDO2 | c.889A>G p.R297G (on ENST00000389060; = p.R310G on NM_194294.2) | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI16 | c.653_654del p.Y218* | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | called by pindel, varscan2
- IGF2R | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHMBP2 | c.784A>T p.I262F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ING1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- INSR | c.4109del p.N1370Tfs*5 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- ITGA8 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, varscan2
- JHY | c.841del p.R281Efs*15 | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | called by mutect2, pindel, varscan2
- JMJD1C | c.1677del p.D560Ifs*10 | Frame Shift Del (DEL) | VAF 69/335 reads (21%) | called by mutect2, pindel, varscan2
- KCNT1 | c.2522A>G p.E841G (on ENST00000488444; = p.E860G on NM_020822.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- KDM3B | c.4981C>T p.R1661* | Nonsense Mutation (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- KHDC4 | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.950dup p.P318Tfs*6 | Frame Shift Ins (INS) | VAF 37/127 reads (29%) | called by mutect2, pindel, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 44/190 reads (23%) | called by mutect2, pindel, varscan2
- LAMB4 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- LATS1 | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 56/219 reads (26%) | called by muse, mutect2, varscan2
- LONRF3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- LRP1 | c.1421G>T p.R474M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LRP1 | c.12152C>T p.A4051V | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRP2 | c.10261_10264del p.Y3421Gfs*24 | Frame Shift Del (DEL) | VAF 56/164 reads (34%) | called by pindel, varscan2
- LRRK2 | c.2858_2860del p.L953del | In Frame Del (DEL) | VAF 28/54 reads (52%) | called by pindel, varscan2
- MDC1 | c.4366C>T p.Q1456* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- MDN1 | c.14768A>T p.E4923V | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MINK1 | c.3338T>C p.M1113T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MPHOSPH8 | c.2028_2029del p.G678Kfs*10 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- MSH2 | c.2148_2149del p.D716Efs*12 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- MSH6 | c.2690del p.N897Ifs*9 | Frame Shift Del (DEL) | VAF 70/235 reads (30%) | called by mutect2, pindel, varscan2
- MTTP | c.88del p.S30Pfs*26 | Frame Shift Del (DEL) | VAF 46/140 reads (33%) | called by mutect2, varscan2
- MUC17 | c.10048A>G p.T3350A | Missense Mutation (SNP) | VAF 230/832 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MUC4 | c.1741A>G p.S581G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MVP | c.156del p.V53Sfs*71 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- MXRA5 | c.4358G>C p.S1453T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH9 | c.2707C>T p.R903W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO1D | c.1612A>G p.S538G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- MYO3A | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYT1 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NACAD | c.4478T>C p.L1493S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, varscan2
- NCOR1 | c.6828_6830del p.D2277del | In Frame Del (DEL) | VAF 57/186 reads (31%) | called by pindel, varscan2
- NHSL1 | c.4553G>A p.R1518Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NUP210L | c.5574del p.F1858Lfs*11 | Frame Shift Del (DEL) | VAF 67/209 reads (32%) | called by mutect2, pindel, varscan2
- OR13C2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- PABPC5 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PARP10 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PAX7 | c.906del p.Y303Tfs*64 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PCDH19 | c.2951C>A p.P984H (on ENST00000373034 / NM_001184880.2; = p.P936H on NM_020766.3) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA2 | c.1034dup p.E346Rfs*9 | Frame Shift Ins (INS) | VAF 80/276 reads (29%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCNX1 | c.5341G>A p.V1781M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PEAR1 | c.1354T>C p.S452P | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PHACTR4 | c.1037del p.P346Hfs*33 (on ENST00000373839 / NM_001350159.2; = p.P356Hfs*33 on NM_023923.4) | Frame Shift Del (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.4598del p.K1533Sfs*34 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, varscan2
- PKD2L2 | c.1793del p.L598Yfs*15 (on ENST00000508883 / NM_001300921.2; = p.L576Yfs*15 on NM_001258448.2) | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.480del p.F160Lfs*28 | Frame Shift Del (DEL) | VAF 50/215 reads (23%) | called by mutect2, pindel, varscan2
- PLEKHG3 | c.800T>C p.F267S (on ENST00000394691; = p.F323S on NM_001308147.2) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PLXNA3 | c.2521del p.R841Afs*93 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PLXNA3 | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLXNB1 | c.4387-2A>C p.X1463_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- PPA2 | c.186dup p.F63Lfs*3 | Frame Shift Ins (INS) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- PRDM7 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | called by mutect2, pindel, varscan2
- PTCHD3 | c.1968G>T p.R656S | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PTPRK | c.3656del p.L1219* (on ENST00000368215 / NM_001291984.2; = p.L1220* on NM_002844.4) | Frame Shift Del (DEL) | VAF 47/134 reads (35%) | called by mutect2, pindel, varscan2
- PXDN | c.2995G>A p.A999T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.5021_5022del p.K1674Rfs*42 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- RPRD2 | c.4194del p.L1399Wfs*14 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- SALL1 | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN2A | c.5597del p.L1866Wfs*35 | Frame Shift Del (DEL) | VAF 81/320 reads (25%) | called by mutect2, pindel, varscan2
- SCP2D1 | c.131G>C p.S44T | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 38/46 reads (83%) | called by mutect2, varscan2
- SGK1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SIPA1L3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SLCO5A1 | c.663del p.Y222Tfs*6 | Frame Shift Del (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- SMG7 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SPTBN1 | c.4487A>G p.D1496G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SRGAP1 | c.490-2A>G p.X164_splice | Splice Site (SNP) | VAF 65/123 reads (53%) | called by muse, mutect2, varscan2
- SUGCT | c.315T>C p.S105= | Splice Region (SNP) | VAF 26/36 reads (72%) | called by muse, mutect2, varscan2
- SUPV3L1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TACC2 | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TAF7L | c.719del p.K240Rfs*26 | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | called by mutect2, varscan2
- TAF9 | c.275del p.L92Yfs*2 | Frame Shift Del (DEL) | VAF 18/151 reads (12%) | called by mutect2, pindel, varscan2
- TAT | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D14 | c.1045+2T>C p.X349_splice | Splice Site (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- TET3 | c.140del p.G47Vfs*46 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- TMEM145 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM63B | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TNXB | c.3724A>G p.M1242V (on ENST00000647633; = p.M995V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TONSL | c.1804del p.L602Sfs*41 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- TPR | c.176del p.K59Rfs*11 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- UBE3C | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- UBR5 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 108/220 reads (49%) | called by muse, mutect2, varscan2
- UBTF | c.475-3del | Splice Region (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- UGT2B11 | c.638del p.N213Ifs*2 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | called by mutect2, pindel, varscan2
- USP24 | c.2741C>T p.S914F | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- USP26 | c.651_652dup p.R218Lfs*6 | Frame Shift Ins (INS) | VAF 53/233 reads (23%) | called by pindel, varscan2
- USP32 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- VPS13C | c.9191dup p.T3065Hfs*3 (on ENST00000644861 / NM_020821.3; = p.T3022Hfs*3 on NM_017684.5) | Frame Shift Ins (INS) | VAF 30/121 reads (25%) | called by mutect2, pindel, varscan2
- VWF | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDFY4 | c.2683G>A p.V895I | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR62 | c.1369A>G p.N457D | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, varscan2
- WDR87 | c.7178T>G p.L2393R | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- WNK1 | c.5083A>G p.T1695A (on ENST00000315939 / NM_018979.4; = p.T1448A on NM_014823.3) | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2
- WNK2 | c.5005C>T p.R1669* (on ENST00000297954 / NM_001282394.1; = p.R1632* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- XAB2 | c.1740dup p.E581* | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- XIRP2 | c.8795G>A p.S2932N (on ENST00000628543; = p.S3107N on NM_152381.6) | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- ZBTB47 | c.1882G>T p.G628* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- ZC3H12A | c.988del p.Q330Sfs*39 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, varscan2
- ZMYND11 | c.1223del p.K408Rfs*11 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- ZNF236 | c.3717G>T p.K1239N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF572 | c.1346T>C p.F449S | Missense Mutation (SNP) | VAF 150/304 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF804B | c.3863del p.P1288Lfs*13 | Frame Shift Del (DEL) | VAF 46/500 reads (9%) | called by mutect2, pindel
- ADAMTSL4 | c.48G>A p.L16= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- AFF4 | c.3339T>C p.A1113= | Silent (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- AHNAK | c.10257C>T p.D3419= | Silent (SNP) | VAF 83/233 reads (36%) | catalogued as rs570439348, COSV99947107; called by muse, mutect2, varscan2
- ALDOA | c.1212G>T p.G404= (on ENST00000642816 / NM_001243177.4; = p.G350= on NM_184041.5) | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- ANK2 | c.2502T>C p.N834= | Silent (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- ANKRD28 | c.237C>T p.H79= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs890304778; called by muse, mutect2, varscan2
- APBA2 | c.2238G>A p.P746= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs751461137, COSV54268788; called by muse, mutect2, varscan2
- ARFGAP3 | c.252C>T p.N84= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs915421557; called by muse, mutect2, varscan2
- ARID3B | c.435G>A p.G145= | Silent (SNP) | VAF 36/229 reads (16%) | catalogued as rs1479587310; called by muse, mutect2, varscan2
- ATP2B3 | c.2958C>T p.N986= | Silent (SNP) | VAF 59/181 reads (33%) | catalogued as rs375637203, COSV54862768; called by muse, mutect2, varscan2
- BCAR3 | c.249G>A p.S83= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs370751140, COSV53078462; called by muse, mutect2, varscan2
- CACNA1A | c.2089C>T p.L697= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV64198236; called by muse, mutect2, varscan2
- CACNB4 | c.639C>T p.Y213= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs753811632, COSV99138029; called by muse, mutect2, varscan2
- CCDC40 | c.1357C>T p.L453= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs768081633; called by muse, mutect2, varscan2
- CD93 | c.168C>T p.N56= | Silent (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- CELSR3 | c.3564G>A p.P1188= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as rs375978730; called by muse, mutect2, varscan2
- CHD6 | c.1213C>T p.L405= | Silent (SNP) | VAF 43/162 reads (27%) | called by muse, mutect2, varscan2
- CHD8 | c.3459G>T p.L1153= (on ENST00000646647 / NM_001170629.2; = p.L874= on NM_020920.4) | Silent (SNP) | VAF 57/146 reads (39%) | called by muse, mutect2, varscan2
- CIC | c.1807C>T p.L603= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- CLIC6 | c.1503C>T p.G501= (on ENST00000360731 / NM_001317009.2; = p.G483= on NM_053277.3) | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs369846247; called by muse, varscan2
- CLIP1 | c.4065C>T p.N1355= (on ENST00000620786 / NM_001247997.1; = p.N1344= on NM_002956.2) | Silent (SNP) | VAF 82/160 reads (51%) | catalogued as rs764488108, COSV56798095; called by muse, varscan2
- CLTC | c.2709C>T p.R903= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs766566397; called by muse, mutect2, varscan2
- COL4A6 | c.1830A>G p.K610= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- COL6A3 | c.8673C>A p.T2891= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs113026406; called by muse, mutect2, varscan2
- CPSF1 | c.1212G>A p.P404= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs781849347; called by muse, mutect2, varscan2
- CRNN | c.765G>A p.K255= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV55124007; called by muse, mutect2, varscan2
- CSMD1 | c.8301G>A p.T2767= (on ENST00000520002; = p.T2766= on NM_033225.6) | Silent (SNP) | VAF 91/179 reads (51%) | catalogued as rs765938760, COSV59315997, COSV59328648, COSV59361465; called by muse, mutect2, varscan2
- CUBN | c.7050T>C p.I2350= | Silent (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- DACH2 | c.276G>A p.P92= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1488930004; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as rs1369010251, COSV60480151; called by muse, varscan2
- DCHS1 | c.39C>T p.G13= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- DCLK3 | c.462T>C p.R154= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, varscan2
- DDX11 | c.1233C>T p.S411= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs772235123, COSV52510821; called by muse, mutect2, varscan2
- DISP3 | c.3957C>T p.G1319= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- DNAH7 | c.9195G>A p.R3065= | Silent (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- DOCK2 | c.4341C>T p.P1447= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs181184602; ClinVar: likely benign; called by muse, mutect2, varscan2
- DPYD | c.75T>C p.H25= | Silent (SNP) | VAF 74/204 reads (36%) | catalogued as rs1325674112; called by muse, mutect2, varscan2
- DSCAM | c.4236C>T p.Y1412= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs199748082; called by muse, mutect2, varscan2
- DST | c.261G>A p.A87= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1351270874; called by muse, mutect2
- EPAS1 | c.1998G>A p.P666= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs368445079; called by muse, mutect2, varscan2
- ERN2 | c.864G>A p.L288= | Silent (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- ESYT2 | c.1680T>G p.P560= (on ENST00000613624; = p.P484= on NM_020728.3) | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- EVC | c.2376G>A p.A792= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1005244629, COSV53829919; ClinVar: likely benign; called by muse, mutect2, varscan2
- EZR | c.1098G>A p.S366= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs148026200; called by muse, mutect2, varscan2
- FANCA | c.3456C>T p.V1152= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs530619438; called by muse, mutect2, varscan2
- FAT2 | c.6081G>A p.A2027= | Silent (SNP) | VAF 53/189 reads (28%) | catalogued as rs192320051, COSV55828781; called by muse, mutect2, varscan2
- FHOD1 | c.1773C>A p.P591= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, varscan2
- FILIP1L | c.1224A>G p.L408= (on ENST00000354552 / NM_182909.3; = p.L168= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 179/576 reads (31%) | called by muse, mutect2, varscan2
- FLNB | c.7449C>T p.N2483= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs201257749, COSV55896621; called by muse, mutect2, varscan2
- FNIP1 | c.1962C>T p.D654= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as rs748028847; called by muse, mutect2, varscan2
- FYCO1 | c.3969G>A p.T1323= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs757351709; called by muse, mutect2, varscan2
- FZD7 | c.1719G>A p.A573= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs753302518; called by muse, mutect2, varscan2
- GCNT2 | c.999C>T p.D333= (on ENST00000379597 / NM_001374747.1; = p.D331= on NM_001491.3) | Silent (SNP) | VAF 56/163 reads (34%) | called by muse, mutect2, varscan2
- GLG1 | c.1440C>T p.C480= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- GTF3C1 | c.1257C>T p.D419= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs764352886, COSV62243532; called by muse, mutect2, varscan2
- HRNR | c.8142A>G p.S2714= | Silent (SNP) | VAF 64/281 reads (23%) | called by muse, mutect2, varscan2
- IFT140 | c.3672G>A p.A1224= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs765766910, COSV63699170; called by muse, mutect2, varscan2
- IGDCC4 | c.1827C>T p.F609= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1319814140, COSV100732917; called by muse, mutect2, varscan2
- IGDCC4 | c.246C>T p.H82= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1350447508; called by muse, mutect2, varscan2
- IGHMBP2 | c.945G>A p.E315= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as rs1364742278; called by muse, mutect2, varscan2
- INSR | c.1032C>T p.G344= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs369231534, COSV57175959; called by muse, mutect2, varscan2
- KAT6A | c.2562T>C p.D854= | Silent (SNP) | VAF 138/286 reads (48%) | catalogued as rs1318538816; called by muse, mutect2, varscan2
- KDM2B | c.2133C>T p.D711= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs371581440; called by muse, mutect2, varscan2
- KIAA1549 | c.1935T>C p.P645= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- KIF24 | c.1581C>T p.H527= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as rs1197331985; called by muse, mutect2
- KSR1 | c.330C>T p.S110= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1435111062; called by muse, mutect2, varscan2
- LAMA4 | c.279C>T p.D93= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as rs397516726, COSV54570965; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMB1 | c.3516C>T p.V1172= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as rs1384830627; called by muse, mutect2, varscan2
- LONRF3 | c.225C>T p.D75= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1368661873; called by muse, mutect2, varscan2
- MAP1A | c.5166T>C p.T1722= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- MAP7D3 | c.528C>T p.S176= | Silent (SNP) | VAF 69/253 reads (27%) | catalogued as COSV100286149, COSV60172941; called by muse, mutect2, varscan2
- MATN4 | c.1299C>T p.R433= (on ENST00000372754; = p.R392= on NM_003833.4) | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1211796247, COSV100637156; called by muse, mutect2, varscan2
- MCF2L | c.3000C>T p.Y1000= (on ENST00000375608; = p.Y968= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs750317392, COSV99995767; called by muse, mutect2, varscan2
- MED25 | c.1002C>T p.G334= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs142842628; ClinVar: likely benign; called by muse, mutect2, varscan2
- MICAL3 | c.1356C>A p.T452= | Silent (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- MTUS2 | c.1443G>A p.T481= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as rs201515125; called by muse, mutect2, varscan2
- MUC16 | c.34113T>C p.S11371= | Silent (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.4914C>T p.S1638= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV101201181; called by muse, mutect2, varscan2
- MUC17 | c.10377A>G p.P3459= | Silent (SNP) | VAF 445/843 reads (53%) | catalogued as rs375029857, COSV100072086; called by muse, mutect2, varscan2
- MUC5B | c.11937C>T p.T3979= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs550767524; called by muse, mutect2, varscan2
- MYB | c.1443C>T p.Y481= | Silent (SNP) | VAF 73/242 reads (30%) | catalogued as rs368381081; called by muse, mutect2, varscan2
- MYO1F | c.1413G>A p.T471= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs201794765; called by muse, varscan2
- NBAS | c.165A>G p.A55= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- NCOR1 | c.2469C>T p.D823= | Silent (SNP) | VAF 59/251 reads (24%) | catalogued as rs377605315; called by muse, mutect2, varscan2
- NEB | c.11706C>T p.D3902= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs1359484405, COSV99413349; called by muse, mutect2, varscan2
- NIPBL | c.3342T>G p.A1114= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- NLRP1 | c.3972C>T p.Y1324= (on ENST00000572272 / NM_033004.4; = p.Y1280= on NM_014922.5) | Silent (SNP) | VAF 83/235 reads (35%) | catalogued as rs953855584; called by muse, mutect2, varscan2
- NOTCH1 | c.4743G>A p.P1581= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs781672648; called by muse, varscan2
- NRP2 | c.2022C>T p.S674= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs1264184930; called by muse, mutect2, varscan2
- NSD2 | c.3906G>A p.S1302= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs754816282; called by muse, mutect2, varscan2
- NWD1 | c.633C>T p.L211= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs773641549; called by muse, mutect2, varscan2
- PALD1 | c.96C>T p.S32= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs531408708, COSV54977739; called by muse, mutect2, varscan2
- PCDHA10 | c.1971G>A p.S657= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs377389644; called by muse, mutect2, varscan2
- PDGFRB | c.2325C>T p.Y775= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs1472203888, COSV55809494; called by muse, mutect2, varscan2
- PDGFRB | c.1743C>T p.Y581= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs776224409, COSV55803977; called by muse, mutect2, varscan2
- PDZD2 | c.7518C>T p.S2506= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs375725638; called by muse, mutect2, varscan2
- PFKP | c.288G>A p.A96= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs757373886; called by muse, varscan2
- PHIP | c.2823G>A p.L941= | Silent (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- PIEZO2 | c.81C>T p.Y27= | Silent (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- PLXNA1 | c.5196C>T p.H1732= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs753922302; called by muse, mutect2, varscan2
- PREX1 | c.4578G>A p.A1526= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs143682562; called by muse, mutect2, varscan2
- PREX1 | c.345C>T p.A115= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs374670295; called by muse, mutect2, varscan2
- QRICH2 | c.4668C>T p.C1556= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs747755073; called by muse, varscan2
- RARS2 | c.1122C>T p.H374= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as rs148229791; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM14 | c.390G>A p.A130= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs374537434; called by muse, mutect2, varscan2
- RBMXL3 | c.834C>T p.D278= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs782067054; called by muse, mutect2, varscan2
- RET | c.1095G>A p.S365= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs201992974, COSV100393912, COSV100394512; ClinVar: likely benign; called by muse, mutect2, varscan2
- RET | c.3315G>A p.A1105= | Silent (SNP) | VAF 43/214 reads (20%) | catalogued as rs766572480, COSV60685983, COSV60703732; called by muse, mutect2, varscan2
- RNF213 | c.1356C>T p.Y452= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs377314891; called by muse, mutect2, varscan2
- RNF213 | c.13659G>A p.T4553= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs763735720; called by muse, mutect2, varscan2
- ROR2 | c.1776C>T p.F592= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs747072020, COSV65217690; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.3045C>T p.N1015= | Silent (SNP) | VAF 92/125 reads (74%) | catalogued as rs747743885, COSV67367519; called by muse, mutect2, varscan2
- SDK1 | c.5181G>A p.P1727= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs375424679; called by muse, mutect2, varscan2
- SF3B2 | c.1686C>T p.G562= | Silent (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- SLC25A44 | c.522G>A p.L174= | Silent (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- SLC8A2 | c.2190G>A p.T730= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52639554; called by muse, mutect2, varscan2
- STAB1 | c.7563C>T p.D2521= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs147274795; called by muse, mutect2, varscan2
- STON2 | c.198G>A p.S66= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs201098551; called by muse, mutect2, varscan2
- SZT2 | c.1881C>T p.F627= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs749921213; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM1 | c.6021C>T p.D2007= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs373431363; called by muse, mutect2, varscan2
- TENM3 | c.1200C>T p.P400= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs748075379, COSV101305340; called by muse, mutect2, varscan2
- TET3 | c.4965C>T p.A1655= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs530313290, COSV69645308; called by muse, mutect2, varscan2
- TGFBR3 | c.2133G>A p.T711= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs755788608, COSV53031928; called by muse, mutect2, varscan2
- TIAM1 | c.747G>A p.P249= | Silent (SNP) | VAF 89/270 reads (33%) | catalogued as rs1375028143, COSV54548155; called by muse, mutect2, varscan2
- TLE1 | c.1488G>A p.T496= | Silent (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- TMEM117 | c.1455G>A p.S485= | Silent (SNP) | VAF 26/408 reads (6%) | catalogued as COSV56915247; called by muse, mutect2
- TNRC6B | c.3675G>A p.R1225= (on ENST00000454349 / NM_001162501.2; = p.R1115= on NM_015088.3) | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- TOPORS | c.3084G>A p.S1028= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as rs377690669; called by muse, mutect2, varscan2
- TRIM46 | c.2202C>T p.G734= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs759762073; called by muse, mutect2, varscan2
- TTN | c.7765T>C p.L2589= (on ENST00000591111; = p.L2543= on NM_003319.4) | Silent (SNP) | VAF 54/155 reads (35%) | catalogued as COSV59932526; called by muse, mutect2, varscan2
- UHRF2 | c.1056G>T p.G352= | Silent (SNP) | VAF 89/244 reads (36%) | called by muse, mutect2, varscan2
- USP26 | c.2587T>C p.L863= | Silent (SNP) | VAF 102/283 reads (36%) | called by muse, mutect2, varscan2
- USP26 | c.642A>C p.V214= | Silent (SNP) | VAF 64/249 reads (26%) | called by muse, varscan2
- USP7 | c.804G>A p.Q268= | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- XAB2 | c.1200G>A p.A400= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs751693059; called by muse, mutect2, varscan2
- XYLB | c.1521G>A p.P507= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as rs201092883; called by muse, mutect2, varscan2
- ZAN | c.7461C>A p.T2487= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- ZFHX3 | c.10527C>T p.G3509= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1237918759, COSV99195006; called by muse, varscan2
- ZNF304 | c.60C>T p.F20= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs374239727; called by muse, mutect2, varscan2
- ZNF473 | c.435G>A p.T145= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs553519000, COSV99568827; called by muse, mutect2, varscan2
- ZNF697 | c.474C>T p.P158= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs939742106; called by muse, mutect2, varscan2
- ZNF827 | c.999G>A p.P333= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs774596211, COSV65225671, COSV65234091; called by muse, mutect2, varscan2
- ACAP3 | c.47+661C>T | Intron (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2
- ADI1 | c.420+200G>A | Intron (SNP) | VAF 16/35 reads (46%) | catalogued as rs1388155239; called by muse, mutect2, varscan2
- ARMC5 | c.1864+156G>A | Intron (SNP) | VAF 17/50 reads (34%) | catalogued as rs754483749; called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 10/46 reads (22%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BRD1 | c.2360-155G>A | Intron (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- CACTIN | c.*156-34A>G | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CCDC144NL | n.1227C>A | RNA (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- CCDC33 | c.1938+431C>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as rs1237263379; called by muse, mutect2, varscan2
- CLUHP5 | n.223A>G | RNA (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- CTNNB1 | c.-7G>A | 5'UTR (SNP) | VAF 20/92 reads (22%) | catalogued as rs976344851; called by muse, mutect2, varscan2
- DNM2 | c.1336-981del | Intron (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- ELN | c.133+78T>C | Intron (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- FANCA | c.*1C>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as rs370357192; ClinVar: uncertain significance; called by muse, varscan2
- FARP1 | c.2274+226C>T | Intron (SNP) | VAF 88/256 reads (34%) | catalogued as rs780703280; called by muse, mutect2, varscan2
- FBRS | c.*490del | 3'UTR (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- GHDC | chr17:42189056 C>T | 3'Flank (SNP) | VAF 9/23 reads (39%) | catalogued as rs972426929; called by muse, mutect2, varscan2
- HBS1L | c.430+2997del | Intron (DEL) | VAF 54/116 reads (47%) | catalogued as rs58798278; called by mutect2, varscan2
- HYDIN | c.-10del | 5'UTR (DEL) | VAF 31/85 reads (36%) | catalogued as rs768899959; called by mutect2, varscan2
- IKBIP | c.297+7961G>T | Intron (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- IRF7 | c.493-9del | Intron (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- ITGA4 | c.319+9G>T | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- LASP1 | c.612+41G>A | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- LATS1 | c.2010+16del | Intron (DEL) | VAF 52/169 reads (31%) | called by mutect2, pindel, varscan2
- MIR7162 | chr10:30365325 C>A | 3'Flank (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- MLIP | c.613-11760G>A | Intron (SNP) | VAF 79/240 reads (33%) | catalogued as rs1171883636; called by muse, mutect2, varscan2
- MTUS1 | c.2288-11del | Intron (DEL) | VAF 52/147 reads (35%) | catalogued as rs762598927; called by mutect2, varscan2
- NTNG1 | c.1087+26del | Intron (DEL) | VAF 48/116 reads (41%) | catalogued as rs753896110; called by mutect2, varscan2
- PITPNM2 | c.2404+713G>A | Intron (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- PLEKHA7 | chr11:16786381 G>A | 3'Flank (SNP) | VAF 47/141 reads (33%) | catalogued as rs1018159790; called by muse, mutect2, varscan2
- POM121L4P | n.698C>T | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- RAVER1 | c.1432-43G>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs981501071; called by muse, varscan2
- SH3TC2 | c.280-1326del | Intron (DEL) | VAF 12/40 reads (30%) | catalogued as rs752479043; called by mutect2, varscan2
- SREBF1 | c.*645A>G | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- SUMO3 | c.222+618G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs962249698; called by muse, varscan2
- TOM1 | c.138-169A>G | Intron (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- TSSC2 | chr11:3413878 C>T | 3'Flank (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- TUBB8B | chr18:50215 G>A | 5'Flank (SNP) | VAF 117/435 reads (27%) | called by muse, varscan2
- USH1C | c.1285-3941G>A | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as rs754366710, COSV99139296; called by muse, mutect2, varscan2
